Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A8EC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A8EC-01A (Primary Tumor).

ICD-0-3
Carcinoma, squamous cell NOS
8070/3
Site Cervix NOS
C53.9
Jan 11/21/13

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

"Biopsy of the cervix":
- Moderately differentiated squamous cell carcinoma.

ICDPA Discrepancy		☒

Source: NCI Genomic Data Commons file 7943bc17-499e-4927-9c3b-f2541c3c546d (TCGA-VS-A8EC.5D347DA8-4A0A-4E09-BCF3-DDD115D741C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).